Surgical pathology report (de-identified scan), TCGA case TCGA-KP-A3W0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site British Columbia Cancer Agency, specimen TCGA-KP-A3W0-01A (Primary Tumor).

[page 1 of 2]
Anatomical Pathology

Case:

MRN:

PHN:

Ordering Physician

Final Diagnosis:

- A. Right upper quadrant biopsy: Fibrous adhesion.
- B. Uterus (with cervix), ovaries and fallopian tubes:
1. High-grade serous carcinoma involving the endometrium and an endometrial polyp.
- a. Tumor invades into the outer half of the myometrium to within 3mm of the uterine serosa.
- b. Lymphatic invasion identified.
- c. Detached clusters of serous carcinoma within the right tubal lumen (see comment).
- d. Cervix negative for tumour.
2. Non-carcinomatous endometrium: atrophic.
3. Myometrial leiomyomas.
4. Bilateral small ovarian serous adenofibromas.
5. Focus of endometriosis on surface of left ovary.
- C. Omental biopsy: Negative for malignancy.
- D. Pelvic washing: Positive for malignant cells.

Comment:

One study of patients with endometrial serous carcinomas found a strong correlation between tumour cells within the tubal lumina and the presence of peritoneal metastases.

Snyder MJ et al. Transtubal spread of serous adenocarcinoma of the endometrium: An underrecognized mechanism of metastasis. Int J Gynecol Pathol 2006;25:155-160.

MD (Resident)
, MD (Pathologist)

ICD03
CARCINOMA, SEROUS, NOS
844113

Clinical History as Provided by Submitting Physician:

Pap serous on endom biopsy

Site: endometrium C54.1

4-25-12

RD

Gross Description:

Received are three containers, each labelled with the patient's name, ~~XXXXXXXXXXXX~~ and demographics.

Container A is labelled, RIGHT UPPER QUADRANT BIOPSY, and consists of an irregular gray-tan tissue fragment, 0.3 cm in diameter, wrapped and submitted in toto as A1.

Container B is labelled, UTERUS + CERVIX + BIL TUBES + OVARIES, and consists of a hysterectomy and bilateral salpingo-oophorectomy specimen.

The specimen weighs 62.4 g. The uterus measures 8 x 4 x 3.5 cm. The serosal surface is tan and smooth. The cervix is grossly unremarkable.

The right ovary measures 2.5 x 1.5 x 1.3 cm and the attached right fimbriated fallopian tube measures 5.5 cm in length x 0.5 cm in diameter. The left ovary

IUPAA Discrepancy		X

[page 2 of 2]
measures 2.2 x 1.9 x 1.4 cm and the attached left fimbriated fallopian tube measures 5 cm in length x 0.4 cm in diameter. Both ovaries and fallopian tubes are grossly unremarkable.

On opening the uterine corpus, the endometrium is thickened and involved by tumor measuring 2 cm in greatest dimension, involving both the anterior and posterior aspects. The tumor does appear to invade the myometrium to a depth of 0.9 cm (0.3 cm from the serosal surface of the uterus). A sample from the tumor is taken for research.

The myometrium measures up to 1 cm in thickness and contains a solitary intramural, 0.3 cm in diameter firm well-circumscribed gray-white myomatous nodule located anteriorly.

Representative sections are submitted as follows:

B1	- right fallopian tube fimbria
B2	- right ovary
B3	- left fallopian tube fimbria
B4	- left ovary
B5	- anterior cervix
B6	- posterior cervix
B7	- posterior cul-de-sac
B8-B10	- endometrial tumor from the anterior wall to show greatest depth of invasion
B11-B13	- endometrial tumor from the posterior wall to show greatest depth of invasion

Remainder of the specimen is saved.

Container C is labelled, OMENTAL BIOPSY, and consists of fatty tissue fragments aggregating to 2.5 cm. Serial sectioning shows unremarkable lobules of adipose tissue. The entire specimen is submitted as C1-C3.

Source: NCI Genomic Data Commons file 056f8ad8-e84a-4475-8264-bd2239af8387 (TCGA-KP-A3W0.8623B627-C3E3-469B-A640-2F8BCFC0B711.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).